Somatic mutation profile of tumor specimen TCGA-X7-A8M4-01A (aliquot TCGA-X7-A8M4-01A-11D-A423-09) from TCGA case TCGA-X7-A8M4, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 41.3 years (15,070 days).
Specimen TCGA-X7-A8M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74fc1874-8e94-4170-badd-e1b8021d7c4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M4-10A (Blood Derived Normal), aliquot TCGA-X7-A8M4-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf35a6dd-cbc0-4546-9391-efe1b4325185

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 24/440 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CCDC3 | c.362T>A p.F121Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs749197079; called by muse, mutect2, varscan2
- TRABD | c.826C>T p.L276= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
